TCGA case TCGA-V4-A9F1 — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94f3d9b0-0ee4-4f6a-a8ff-ce7a4d8fab76

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 46 years; Year of birth: 1966; Vital status: Dead; Days to death: 1,850 days (5.1 years); Year of death: 2017.

Diagnoses (1)
1. Epithelioid cell melanoma: ICD-O-3 morphology code: 8771/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 46.1 years (16,852 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIB; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,850 days (5.1 years); Sites of involvement: Eye, Choroid.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: >90%; Extrascleral extension present: No; Measurement type: Echographic; Tumor depth measurement: 8.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 16.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -15 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Days to treatment start: 22 days; Days to treatment end: 147 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 147 days; Number of cycles: 5; Treatment dose: 75 mg/m2; Reason treatment ended: Course of Therapy Completed.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,161 days (3.2 years); Residual disease: R0; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dacarbazine; Treatment intent type: Salvage; Days to treatment start: 1,536 days (4.2 years); Days to treatment end: 1,603 days (4.4 years); Number of cycles: 2; Treatment dose: 1,156 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 556 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 661 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 938 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,143 days (3.1 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,143 days (3.1 years).
- Days to follow up: 1,850 days (5.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 50 kg; Height: 150 cm; BMI: 22.2.
- Eye color: Brown.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-V4-A9F1-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9F1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9F1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 8 mm; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 938 days; disease-specific survival: no event (censored), 938 days; progression-free interval: no event (censored), 938 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9F1-01A-11D-A39V-01): tumor purity 0.89, ploidy 1.95, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3, 13, 6p; Gain 8q
- cancer type 1: breast ca
- days to metastasis: 1143
- days to outcome: 1834
- days to pharm therapy imaging 2: 1595
- days to procedure 1: -15
- days to procedure 2: 1161
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 2: deticene
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 5
- number cycles 2: 2
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy dose units 2: mg
- pharm therapy evaluated by imaging 2: yes
- pharm therapy imaging type 2: MRI
- pharm therapy status 1: completed as planned
- pharm therapy status 2: treatment discontinued
- pharm therapy status reason 2: Lack of Response
- procedure type 2: hemi hepatectomy
- resection status 1: R0
- resection status 2: R0
- smoking status: non-smoker
- staging system: AJCC
- t stage: T3b
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
- unresectable 2: no
